Somatic mutation profile of tumor specimen ALCH-B3IH-TTP1-A (aliquot ALCH-B3IH-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3IH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,215 days).
Specimen ALCH-B3IH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f36647e6-ab99-4f56-aded-655933215c62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3IH-NB1-A (Blood Derived Normal), aliquot ALCH-B3IH-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97df01d8-f59f-4732-a2e8-52e9b854d053

The open-access MAF lists 100 somatic variants for this specimen: 65 protein-altering or splice-affecting, 26 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 26, Intron 8, Nonsense Mutation 6, Nonstop Mutation 1, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.4676A>T p.E1559V | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs760768052; called by muse, mutect2, varscan2
- AKAP12 | c.3980A>T p.K1327M | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV53573194; called by muse, mutect2
- ALPK2 | c.3661G>C p.E1221Q | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV100864318; called by muse, mutect2
- CHST6 | c.111del p.E38Rfs*32 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as COSV100178456; called by mutect2, varscan2
- DERA | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs746601720; called by mutect2, varscan2
- DPP6 | c.1331G>A p.R444Q (on ENST00000377770 / NM_001364500.2; = p.R382Q on NM_001936.5) | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.09); catalogued as rs769118239; called by muse, mutect2, varscan2
- EYA1 | c.522A>T p.Q174H | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV58172165; called by muse, mutect2
- INVS | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1397635177; called by muse, mutect2, varscan2
- NOD2 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as CM030413, COSV56055090; called by muse, mutect2, varscan2
- OR51L1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775959370; called by muse, mutect2
- OR52B2 | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs766550488; called by muse, mutect2, varscan2
- OR8H2 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs1474937447; called by muse, mutect2
- PADI1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779590846, COSV64937737; called by muse, mutect2, varscan2
- PRDM9 | c.2653G>C p.E885Q | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs745401689; called by muse, mutect2, varscan2
- RPL35A | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 9/290 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs1047441058, COSV54564029; called by muse, mutect2
- SDHA | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 49/696 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53774383; called by muse, mutect2
- SFMBT1 | c.1883C>G p.S628C | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1424896492; called by muse, mutect2
- SLC39A4 | c.1391C>T p.P464L (on ENST00000301305 / NM_001374839.1; = p.P439L on NM_017767.3) | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1554872599, COSV52777894; called by muse, mutect2
- UNC45B | c.2086C>G p.H696D | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV52092912; called by muse, mutect2
- ZNF398 | c.1588C>T p.R530W (on ENST00000475153 / NM_170686.3; = p.R359W on NM_020781.4) | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs1301162799, COSV60065295; called by muse, mutect2
- ABCC2 | c.1870A>C p.T624P | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- AOAH | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.023); called by muse, mutect2
- AP1M2 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BRWD3 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CACNA2D1 | c.2983G>C p.D995H (on ENST00000356253 / NM_001366867.1; = p.D983H on NM_000722.4) | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CASKIN2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDKL5 | c.2443A>G p.S815G | Missense Mutation (SNP) | VAF 29/549 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- CIB1 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- CLDND2 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- CPNE3 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 20/487 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2
- CREB5 | c.410C>A p.S137* (on ENST00000357727 / NM_182898.4; = p.S130* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- DCAF16 | c.649T>C p.*217Qext*14 | Nonstop Mutation (SNP) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- DCLRE1B | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by mutect2, varscan2
- DGKD | c.1150G>T p.G384C (on ENST00000264057 / NM_152879.3; = p.G340C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH8 | c.2819C>G p.T940S | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DNM2 | c.1792A>G p.K598E (on ENST00000355667 / NM_001005360.3; = p.K594E on NM_004945.3) | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2
- DST | c.10021C>A p.L3341I | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2
- FBXL7 | c.1007T>G p.F336C | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN1 | c.1701C>G p.D567E | Missense Mutation (SNP) | VAF 49/389 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECTD3 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- HNF4A | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- ITPKB | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- KRT73 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2
- MICU2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 35/396 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.073); called by muse, mutect2
- MICU2 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2
- NHSL1 | c.4142A>G p.H1381R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.144); called by muse, mutect2
- NLGN3 | c.635T>G p.M212R (on ENST00000358741 / NM_181303.2; = p.M192R on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.702); called by muse, mutect2
- OAS3 | c.2491G>C p.E831Q | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, mutect2
- OR2T4 | c.358G>C p.G120R | Missense Mutation (SNP) | VAF 14/383 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- OR2T6 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PASK | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SDHA | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 98/1432 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SEMA3E | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINH1 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 12/462 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.253); called by muse, mutect2
- SLC10A7 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC25A31 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, varscan2
- TNFSF15 | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.237); called by muse, mutect2
- TSC22D2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- UBFD1 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WARS1 | c.364A>G p.R122G | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2
- WNK1 | c.932+2dup p.X311_splice | Splice Site (INS) | VAF 38/336 reads (11%) | called by mutect2, varscan2
- XIAP | c.334A>C p.N112H | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ZBTB41 | c.976A>T p.K326* | Nonsense Mutation (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF729 | c.3266C>G p.S1089* | Nonsense Mutation (SNP) | VAF 26/364 reads (7%) | called by muse, mutect2
- ARHGAP24 | c.639G>A p.L213= (on ENST00000395184 / NM_001025616.3; = p.L120= on NM_031305.3) | Silent (SNP) | VAF 21/418 reads (5%) | called by muse, mutect2
- ARHGAP25 | c.987T>C p.P329= (on ENST00000409202 / NM_001007231.3; = p.P321= on NM_014882.3) | Silent (SNP) | VAF 24/198 reads (12%) | called by mutect2, varscan2
- C6orf118 | c.1317A>G p.Q439= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- CD80 | c.382C>A p.R128= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99958236; called by muse, mutect2
- CDH15 | c.2349G>T p.P783= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- CELF1 | c.1104A>G p.Q368= (on ENST00000358597 / NM_001376422.1; = p.Q364= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 38/322 reads (12%) | catalogued as rs752515334; called by muse, mutect2, varscan2
- FLG | c.8598C>T p.D2866= | Silent (SNP) | VAF 38/694 reads (5%) | called by muse, mutect2
- GPR55 | c.867C>T p.Y289= | Silent (SNP) | VAF 23/240 reads (10%) | catalogued as rs1487083073; called by muse, mutect2
- KRT16 | c.744G>A p.L248= | Silent (SNP) | VAF 11/254 reads (4%) | called by muse, mutect2
- LRRC14B | c.84C>T p.S28= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs1345976253; called by muse, mutect2
- MMP19 | c.216G>T p.L72= | Silent (SNP) | VAF 12/253 reads (5%) | called by muse, mutect2
- OR10A5 | c.807T>G p.P269= | Silent (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
- PASK | c.1347G>T p.V449= | Silent (SNP) | VAF 18/306 reads (6%) | catalogued as rs1363951669; called by muse, mutect2
- PCDHGA9 | c.1164G>A p.E388= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as rs751598967, COSV53940350; called by muse, mutect2
- PLA2G4F | c.567C>A p.L189= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- PTPRO | c.1434C>T p.S478= | Silent (SNP) | VAF 25/284 reads (9%) | catalogued as rs1158109821; called by muse, mutect2
- SETD1A | c.3927G>T p.T1309= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV52686834, COSV52691381; called by mutect2, varscan2
- SLC6A19 | c.1035C>T p.I345= | Silent (SNP) | VAF 50/574 reads (9%) | called by muse, mutect2
- SPG11 | c.1632A>G p.T544= | Silent (SNP) | VAF 41/328 reads (13%) | catalogued as rs368683333; called by muse, mutect2, varscan2
- TRIM68 | c.250C>T p.L84= | Silent (SNP) | VAF 37/426 reads (9%) | called by muse, mutect2
- UNC45B | c.2085C>A p.A695= | Silent (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- UPF2 | c.1722G>A p.Q574= | Silent (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
- USP26 | c.663A>G p.Q221= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- WDR11 | c.2382G>A p.V794= | Silent (SNP) | VAF 14/434 reads (3%) | called by muse, mutect2
- ZDHHC9 | c.867C>T p.G289= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- ZNF879 | c.249A>T p.A83= | Silent (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- ADAM10 | c.207-9849G>T | Intron (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- HBD | c.-29+221T>A | Intron (SNP) | VAF 21/206 reads (10%) | catalogued as rs1479889287; called by muse, mutect2, varscan2
- IGFN1 | c.1242-539C>T | Intron (SNP) | VAF 10/314 reads (3%) | called by muse, mutect2
- MYO7B | c.6249+182G>A | Intron (SNP) | VAF 9/84 reads (11%) | catalogued as rs1293765254; called by muse, mutect2, varscan2
- NF1 | c.1721+27C>G | Intron (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- OR52A4P | n.863C>A | RNA (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- PPP2R2B | c.1052+881G>T | Intron (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2
- PPP2R2B | c.1052+880G>T | Intron (SNP) | VAF 29/265 reads (11%) | called by muse, mutect2
- PSMD3 | c.1476+380G>C | Intron (SNP) | VAF 34/309 reads (11%) | called by muse, mutect2, varscan2
